Gene-level copy-number profile of tumor specimen HCM-BROD-0834-C43-06A from HCMI case HCM-BROD-0834-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 78.9 years (28,828 days).
Specimen HCM-BROD-0834-C43-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f056b439-5a74-43c9-a454-9202abe3d0b1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0834-C43-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/717b5495-87aa-4200-98fd-570ed05d4966

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 13; copy number 2: 5,952; copy number 3: 48; copy number 4: 49,821; copy number 5: 355; copy number 6: 1,387; copy number 7: 60; copy number 8: 84; copy number 9: 2; copy number 10: 1,174; copy number 12: 9.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,966,929–21,967,751, 1 gene (within-gene range 0–2): CDKN2A-DT.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,185 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:58,805,412–59,760,263, 10 genes, copy number 10: TOX, RNU4-50P, AC105150.1, AC090152.1, AC087698.1, RNA5SP267, AC087664.3, AC087664.1, AC087664.2, AC107934.1.
- chr8:59,893,856–60,516,795, 6 genes, copy number 10: AC022709.1, AC021393.1, SLC2A13P1, CA8, LINC01301, PDCL3P1.
- chr8:69,424,849–70,403,808, 21 genes, copy number 10: LINC01603, AC022790.1, SULF1, SLCO5A1, RN7SKP29, AC091047.1, AC079089.3, AC079089.1, Metazoa_SRP, AC079089.2, RN7SL675P, RNA5SP270, AC090574.1, SDCBPP2, SUMO2P20, PRDM14, RNU1-101P, H2AZP2, NCOA2, BTF3P12, RNY3P14.
- chr8:72,196,334–145,066,685, 1,117 genes, copy number 10 (broad region; genes not listed).
- chr9:6,215,786–6,727,438, 17 genes, copy number 10 (within-gene range 2–10): IL33, AL360221.1, SELENOTP1, TPD52L3, UHRF2, AL133480.1, GLDC, RN7SL25P, AL353718.1, RPL23AP57, AL162411.1, RN7SL123P, RPS3AP54, RNF2P1, RPL35AP20, LINC02851, AL354707.1.
- chr9:11,618,496–12,058,227, 2 genes, copy number 9: AL592227.1, AL353595.1.
- chr9:14,737,152–15,146,401, 9 genes, copy number 12: FREM1, AL512643.2, AL512643.1, RNU6-1260P, CLCN3P1, LDHAP4, AL592293.1, PSIP1P1, RNU6-559P.
- chr22:26,858,634–26,968,763, 3 genes, copy number 10 (within-gene range 2–10): LINC01422, Z97353.1, Z97353.2.

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
